Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4160, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4160-01A (Primary Tumor).

[page 1 of 2]
....
Other Related Data:

Billing Type: [REDACTED]

Financial Number: [REDACTED]

Clinical Diagnosis & History:

Left renal tumor.

Specimens Submitted:

1: SP: Lt. kidney and adrenal gland [REDACTED]

2: SP: Para-aortic lymph nodes [REDACTED]

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND, LEFT; NEPHRECTOMY AND ADRENALECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL) TYPE, NUCLEAR GRADE II/IV. THE PATTERN OF GROWTH IS ACINAR. THE TUMOR GREATEST DIAMETER IS 4.5 CM. THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. THE ADRENAL GLAND SHOWS FOCAL NODULAR HYPERPLASIA.
- 2) LYMPH NODES, PARA-AORTIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- [REDACTED]
- [REDACTED]

Gross Description:

- [REDACTED] [REDACTED]
- 1) The specimen is received fresh for frozen section, labeled "Left kidney and adrenal gland". It consists of a left kidney, segment of ureter, fragments of the renal blood vessel, perinephric adipose tissue and a portion of adrenal gland, weighing 450 grams. The kidney measures 11.0 x 6.0 x 5.0 cm. The portion of ureter measures 7.0 cm in length and 0.5 cm in circumference. Sectioning of the kidney reveals a well-circumscribed tumor which grossly breaks through the renal

[page 2 of 2]
capsule and extends to the perinephric adipose tissue, coming within 0.1 cm from the inked Gerota's fascia. The tumor is composed of pink-red to bright yellow, soft to focally fibrous parenchyma. The dimension of the tumor is 4.5 x 3.0 x 0.5 cm and it involves the mid-lower portion of the kidney. Grossly, the collecting system is free of tumor. The urothelium of the pelvis and ureter is pink-tan and smooth. The hilar region of the kidney is free of tumor. The renal vein is free of tumor. The rest of the renal parenchyma is grossly unremarkable. The portion of renal gland measures 3.5 x 2.0 x 1.0 cm. Serial sectioning of the adrenal gland reveals intramedullary hemorrhage; otherwise, the parenchymal adrenal gland is unremarkable. No lymph nodes are identified at the region of the kidney. Representative sections are submitted. A small portion of tumor is taken for TPS. Tumor is also fixed in glutaraldehyde for EM studies. Gross photographs of the specimen are taken.

Summary of Sections:

FSC - Frozen section control
SM - Ureteral and renal blood vessel surgical margin
TGF - Tumor closest to inked Gerota's fascia
T - Representative sections of tumor
-- - Representative sections of renal parenchyma
AG - Representative sections of adrenal gland

2) The specimen is received in formalin, labeled "Para-aortic Lymph Nodes". It consists of pieces of fibroadipose tissue measuring 7 x 6 x 2.5 cm in aggregate. On sectioning, multiple lymph nodes ranging in size from 0.6 to 4.5 cm are identified. The largest lymph node is almost 99% replaced by the adipose tissue. Lymph nodes are submitted in two blocks.

Summary of Sections:

LNS - lymph nodes
LN - lymphoid tissue from the largest lymph node

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	AG		1	M	N
	FSC		1	1	
	RS		1	2	
	SM		1	3	
	T		3	M	
	TGF		3	M	
2	LN		1	M	Y
	LNS		1	M	

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA.
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file ac96d9d8-1a40-4c6d-8273-2a0e8303590b (TCGA-BP-4160.B8013D39-CF8A-4060-BE53-1330D6306E31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).